TCGA case TCGA-CJ-4636 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2d8da564-e69f-4bfa-a1d3-227a294f3886

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 51 years; Vital status: Alive.

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 51.7 years (18,878 days); Year of diagnosis: 2004; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G3; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 4.
2. Basaloid squamous cell carcinoma: ICD-O-3 morphology code: 8083/3; Classification of tumor: Prior primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,924 days (5.3 years); Disease response: Tumor Free.
- ECOG performance status: 0; Timepoint: Preoperative.

Molecular and laboratory tests
- Leukocytes: Normal.
- Lactate Dehydrogenase: Normal.
- Hemoglobin: Normal.
- Calcium: Normal.
- Platelets: Normal.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CJ-4636-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 3; Intermediate dimension: 0.8; Shortest dimension: 0.5.
  Slide TCGA-CJ-4636-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
  Slide TCGA-CJ-4636-01A-01-BS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
  Slide TCGA-CJ-4636-01A-02-BS2: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
- Sample TCGA-CJ-4636-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CJ-4636-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 3.3; Intermediate dimension: 0.6; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Lymph nodes examined: Yes.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: site not stated; Other malignancy histological type: Basaloid Squamous Cell.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,924 days; disease-specific survival: no event (censored), 1,924 days; progression-free interval: no event (censored), 1,924 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CJ-4636-01A-02D-1322-01): tumor purity 0.58, ploidy 2.14, whole-genome doublings 0.
